Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5712, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5712-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Left renal cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left radical nephrectomy.

FINAL DIAGNOSIS:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE (17.8 CM).
- B. FUHRMAN NUCLEAR GRADE IS 3 OF 4.
- C. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- D. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. THE NON-NEOPLASTIC KIDNEY DEMONSTRATES CHANGES OF HYDRONEPHROSIS.
- H. THE ADRENAL GLAND IS NOT SUBMITTED.
- I. HISTOPATHOLOGIC STAGE: pT2 NX MX
- J. TNM HISTOLOGIC GRADE = G3.

SYNOPTIC - PRIMARY Kidney/Renal Pelvis/Ureter TUMORS

- A. Side: 2 1. Right 2. Left
- B. Location: 1
- 1. Kidney (parenchyma - cortex/medulla)
- 2. Kidney (pelvis)
- 3. Ureter
- 4. Kidney and ureter
- C. Procedure: 3
- 1. Partial nephrectomy
- 2. Simple nephrectomy
- 3. Radical nephrectomy
- 4. Ureterectomy
- 5. Other
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): # cm
- E. Type of malignant neoplasm: 1
- 1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)
- 2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)
- 3. Renal cell carcinoma, chromophobe cell type
- 4. Renal cell carcinoma, oncocytic
- 5. Renal cell carcinoma, sarcomatoid
- 6. Collecting duct carcinoma
- 7. Urothelial carcinoma, TCCa (non-invasive)
- 8. Urothelial carcinoma, TCCa (invasive ± in-situ)
- 9. Urothelial carcinoma, squamous carcinoma
- 10. Urothelial carcinoma, adenocarcinoma
- 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
- 12. Urothelial carcinoma, mixed
- 13. Juxtaglomerular cell tumor
- 14. Wilms' tumor
- 15. Rhabdoid tumor
- 16. Clear cell sarcoma
- 17. Congenital mesoblastic nephroma
- 18. Sarcoma (non-clear cell)
- 19. Lymphoma/leukemia
- 20. Other
- F. Histologic grade
- F1. Fuhrman grade (for RCC; grades 1-4): 3
- F2. Ash grade (grade 1-4): #
- F3. WHO grade (grade 1-3): # (for TCCa)
- F4. 1998 WHO/ISUP Classification: #
- 1. LMP 2. LG 3. HG
- F5. Other malignant neoplasms (grades 1-3): #
- G. Non-neoplastic and other conditions: 7 (HYDRONEPHROSIS)
- 1. Glomerulopathy
- 2. Interstitial nephritis
- 3. Pyelonephritis
- 4. Nephrolithiasis
- 5. Papillary necrosis
- 6. Chronic parenchymal disease
- 7. Other
- H. Margins of resection: 2
- 1. Positive 2. Negative
- I. Mitotic activity: 1 per 10 high power fields
- J. Angiolymphatic invasion
- J1. Macroscopic (e.g., renal vein thrombus): 2
- 1. Positive 2. Negative
- J2. Microscopic: 2
- 1. Positive 2. Negative
- K. Number of positive lymph nodes: 0
- L. Total number of lymph nodes examined: 0
- M. Extracapsular spread of lymph node metastases: #
- 1. Yes 2. No
- N. Adrenal gland:
- N1. Present: 2
- 1. Yes 2. No
- N2. Involvement by renal neoplasm: #
- 1. Yes 2. No 3. Not Applicable
- N3. Other adrenal pathology: #
- 1. Yes 2. No 3. Not applicable
- O. TNM stage: T 2 N X M X

Source: NCI Genomic Data Commons file 77ea4fd3-04c3-427d-bfbf-970687919b9b (TCGA-B0-5712.2A7F0B05-442E-4E1E-99AF-29ADA019DF35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).